Gene-level copy-number profile of tumor specimen HTMCP-02-28-01225-01A from CGCI case HTMCP-02-28-01225, project CGCI-HTMCP-LC (HIV+ Tumor Molecular Characterization Project - Lung Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 69.9 years (25,514 days).
Specimen HTMCP-02-28-01225-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6f460de7-b8ec-4c96-9953-f625eae3e2a9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-02-28-01225-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,251 have no estimate.
https://portal.gdc.cancer.gov/files/1efebc33-2671-41e1-b932-162138152576

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 1,661; copy number 2: 17,249; copy number 3: 17,925; copy number 4: 18,451; copy number 5: 2,864; copy number 6: 197; copy number 7: 4; copy number 8: 9; copy number 9: 1; copy number 11: 1.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:21,927,657–21,951,323, 2 genes: NF1P2, MIR5701-3.
- chr15:34,379,068–34,521,791, 8 genes (within-gene range 0–2): GOLGA8A, MIR1233-1, AC025678.1, AC025678.2, AC025678.3, HNRNPLP2, FSCN1P1, DNM1P5.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:40,883,634–40,883,763, 1 gene, copy number 9: AL353626.2.
- chr10:95,141,925–95,168,425, 1 gene, copy number 11: AL157834.4.

Autosomal genes at a single copy (total copy number 1): 798. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
